Gene-level copy-number profile of tumor specimen TCGA-JY-A93D-01A from TCGA case TCGA-JY-A93D, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.5 years (18,813 days).
Specimen TCGA-JY-A93D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.a4d2e53b-7f9f-4596-87de-005ed6c5b6c4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JY-A93D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 828 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c56f889d-89be-446a-a3f2-dfd11366a832

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 1,895; copy number 3: 15,119; copy number 4: 15,926; copy number 5: 15,128; copy number 6: 6,040; copy number 7: 2,876; copy number 8: 848; copy number 9: 1,096; copy number 10: 362; copy number 11: 41; copy number 13: 23; copy number 15: 166; copy number 19: 50; copy number 20: 2; copy number 31: 2; copy number 37: 3; copy number 41: 21; copy number 52: 34; copy number 53: 32; copy number 68: 6; copy number 87: 32; copy number 111: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JY-A93D-01A-11D-A386-01): tumor purity 0.33, ploidy 2.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,959 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:104,395,002–124,989,325, 358 genes, copy number 10 (broad region; genes not listed).
- chr7:28,118,113–37,449,249, 169 genes, copy number 11–15 (broad region; genes not listed).
- chr7:63,011,463–67,362,950, 197 genes, copy number 9 (broad region; genes not listed).
- chr8:8,895,813–13,604,610, 155 genes, copy number 20–111 (within-gene range 6–111) (broad region; genes not listed).
- chr8:15,325,296–16,000,324, 7 genes, copy number 15: AC103851.1, TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2.
- chr8:17,246,931–17,861,069, 17 genes, copy number 13 (within-gene range 6–13): VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1, MIR548V, AC124069.1, RNA5SP256, AC027117.2, AC027117.1.
- chr8:19,404,161–20,229,877, 9 genes, copy number 13–19: CSGALNACT1, AC090541.1, INTS10, LPL, AC100802.1, RPL30P9, SLC18A1, ATP6V1B2, RNU6-892P.
- chr9:10,948,372–11,436,244, 4 genes, copy number 10: AL162413.1, AKAP8P1, AL451129.1, AL355672.1.
- chr12:16,989,126–17,711,046, 12 genes, copy number 13–68: SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA.
- chr12:20,810,702–27,972,733, 132 genes, copy number 11–52 (within-gene range 3–52) (broad region; genes not listed).
- chr20:30,214,765–64,313,132, 899 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
